Somatic mutation profile of tumor specimen 0DIZWC from CCDI case PBBVXF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 14.6 years (5,335 days).
Specimen 0DIZWC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32f292e7-270b-4a10-b287-15171449aa3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIZVT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca92002-a0df-47b9-b544-88d6b5d04e83

The open-access MAF lists 320 somatic variants for this specimen: 214 protein-altering or splice-affecting, 47 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 47, Nonsense Mutation 45, Intron 35, 3'UTR 13, 5'UTR 7, Splice Site 5, 3'Flank 2, 5'Flank 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 281/370 reads (76%) | catalogued as rs1567556752, CM120852, COSV52811974, COSV52991347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.616C>A p.H206N | Missense Mutation (SNP) | VAF 179/764 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1388136191, COSV100488590; called by muse, mutect2, varscan2
- ADCY2 | c.3055G>T p.D1019Y | Missense Mutation (SNP) | VAF 359/928 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57878427; called by muse, mutect2, varscan2
- ATAD2 | c.2981G>T p.R994I | Missense Mutation (SNP) | VAF 387/501 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54885114; called by muse, mutect2, varscan2
- ATP7A | c.4169C>A p.S1390Y | Missense Mutation (SNP) | VAF 69/930 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454244; called by muse, mutect2
- CDH23 | c.4078G>T p.A1360S | Missense Mutation (SNP) | VAF 58/1024 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as COSV56486751; called by muse, mutect2
- CDH9 | c.1515G>T p.L505F | Missense Mutation (SNP) | VAF 145/373 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV50255903; called by muse, mutect2, varscan2
- CENPQ | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV59921106; called by muse, mutect2
- DHX35 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 357/922 reads (39%) | catalogued as rs757176996; called by muse, mutect2, varscan2
- DMBT1 | c.913G>T p.G305* | Nonsense Mutation (SNP) | VAF 485/1089 reads (45%) | catalogued as COSV57555316; called by muse, mutect2, varscan2
- DMD | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 265/629 reads (42%) | catalogued as COSV55858217, COSV55869817; called by muse, mutect2, varscan2
- DNAH6 | c.5512G>T p.D1838Y | Missense Mutation (SNP) | VAF 20/501 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52886220; called by muse, mutect2
- DNAI1 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 247/563 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV104386630; called by muse, mutect2, varscan2
- DOCK1 | c.226G>T p.G76W | Missense Mutation (SNP) | VAF 38/531 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99726652; called by muse, mutect2
- DOCK4 | c.5611G>T p.E1871* | Nonsense Mutation (SNP) | VAF 276/603 reads (46%) | catalogued as COSV70238571; called by muse, mutect2, varscan2
- ESPL1 | c.1029C>A p.F343L | Missense Mutation (SNP) | VAF 168/405 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs747997021; called by muse, mutect2, varscan2
- FGF3 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 63/749 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV61926299; called by muse, mutect2
- FHAD1 | c.3669C>A p.F1223L | Missense Mutation (SNP) | VAF 29/558 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as COSV100119454; called by muse, mutect2
- FLG | c.8302G>T p.E2768* | Nonsense Mutation (SNP) | VAF 54/385 reads (14%) | catalogued as COSV64244968, COSV64251414; called by muse, mutect2, varscan2
- GMPR2 | c.976G>T p.E326* (on ENST00000355299 / NM_001351022.2; = p.E344* on NM_016576.5) | Nonsense Mutation (SNP) | VAF 168/754 reads (22%) | catalogued as COSV57468341; called by muse, mutect2, varscan2
- HERC1 | c.8878G>T p.E2960* | Nonsense Mutation (SNP) | VAF 68/702 reads (10%) | catalogued as COSV71245761, COSV71250831; called by muse, mutect2
- KIF1B | c.3061G>T p.D1021Y (on ENST00000377086 / NM_001365952.1; = p.D975Y on NM_015074.3) | Missense Mutation (SNP) | VAF 345/459 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV55805544; called by muse, mutect2, varscan2
- LTN1 | c.1547C>A p.S516Y | Missense Mutation (SNP) | VAF 406/793 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV63733660; called by muse, mutect2, varscan2
- MGA | c.6409G>T p.E2137* (on ENST00000219905 / NM_001164273.1; = p.E1928* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 547/628 reads (87%) | catalogued as COSV54950462; called by muse, mutect2, varscan2
- MUC17 | c.7292C>A p.S2431Y | Missense Mutation (SNP) | VAF 310/905 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60284710; called by muse, mutect2, varscan2
- MYH7B | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 572/1358 reads (42%) | catalogued as COSV53421782, COSV99483356; called by muse, mutect2, varscan2
- NLRP4 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 373/942 reads (40%) | catalogued as COSV56709125; called by muse, mutect2, varscan2
- NLRP8 | c.2748G>T p.M916I | Missense Mutation (SNP) | VAF 245/612 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV52590065; called by muse, mutect2, varscan2
- NPC1L1 | c.2736C>A p.S912R | Missense Mutation (SNP) | VAF 330/719 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1212778355; called by muse, mutect2, varscan2
- NSMF | c.1474C>A p.P492T (on ENST00000371475 / NM_001130969.3; = p.P490T on NM_015537.4) | Missense Mutation (SNP) | VAF 317/840 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1564257001; called by muse, mutect2, varscan2
- OAS1 | c.1029G>T p.W343C | Missense Mutation (SNP) | VAF 420/1072 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52536215; called by muse, mutect2, varscan2
- OR7G3 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100555787; called by muse, mutect2
- PCDHGB7 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 21/427 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV54031326; called by muse, mutect2
- PDCL3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 468/580 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs777385726, COSV51809791; called by muse, mutect2, varscan2
- PIGR | c.2132G>T p.G711V | Missense Mutation (SNP) | VAF 194/452 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757466228, COSV62904297; called by muse, mutect2, varscan2
- PITHD1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 34/298 reads (11%) | catalogued as COSV99862243; called by mutect2, varscan2
- PIWIL3 | c.2270C>A p.A757D | Missense Mutation (SNP) | VAF 197/271 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs750992968; called by muse, mutect2, varscan2
- PVRIG | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 391/977 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140827025; called by muse, mutect2, varscan2
- RGPD8 | c.3469G>T p.E1157* | Nonsense Mutation (SNP) | VAF 57/302 reads (19%) | catalogued as COSV100222022; called by muse, mutect2, varscan2
- RGPD8 | c.2794C>A p.Q932K | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT tolerated (0.36); PolyPhen benign (0.17); catalogued as COSV56902335; called by mutect2, varscan2
- RHOXF1 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 333/764 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV54294653; called by muse, mutect2, varscan2
- RNF10 | c.2094C>A p.F698L | Missense Mutation (SNP) | VAF 484/1165 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV58048381; called by muse, mutect2, varscan2
- RTL3 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 298/700 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV58185113; called by mutect2, varscan2
- SERPINB12 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 303/388 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54032523; called by muse, mutect2, varscan2
- SLC23A1 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 48/1738 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV62297296; called by muse, mutect2
- SLC7A8 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 277/639 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV57552873, COSV57552925; called by muse, mutect2, varscan2
- SLC9B2 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 282/734 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV100294243, COSV60020106; called by mutect2, varscan2
- SNX18 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 238/606 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs374497194; called by mutect2, varscan2
- STAT2 | c.1485G>T p.L495F | Missense Mutation (SNP) | VAF 315/777 reads (41%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.917); catalogued as COSV58475524; called by muse, mutect2, varscan2
- STAT4 | c.545-1G>T p.X182_splice | Splice Site (SNP) | VAF 240/309 reads (78%) | catalogued as COSV61832282; called by muse, mutect2, varscan2
- TACR3 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 465/1029 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs200736098, COSV59200720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM1 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 263/605 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64441921; called by muse, mutect2, varscan2
- TIFAB | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 312/785 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.389); catalogued as rs1364240745; called by muse, mutect2, varscan2
- TPRKB | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 257/338 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs542871596; called by muse, mutect2, varscan2
- TRIM64C | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 500/675 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV73267232; called by muse, mutect2, varscan2
- XIAP | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 366/901 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as rs1173359687; called by muse, mutect2, varscan2
- ZBBX | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 25/227 reads (11%) | catalogued as COSV56793501; called by muse, mutect2, varscan2
- ZP4 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 214/516 reads (41%) | catalogued as COSV63913850; called by mutect2, varscan2
- AAAS | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 328/829 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AARS1 | c.1657G>T p.D553Y | Missense Mutation (SNP) | VAF 369/903 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ABCA13 | c.13369G>T p.G4457* | Nonsense Mutation (SNP) | VAF 26/514 reads (5%) | called by muse, mutect2
- ADGB | c.3862G>T p.A1288S | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.051); called by muse, mutect2
- ANKRD2 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 42/508 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by muse, mutect2
- APEX1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 64/996 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2
- ARAP2 | c.1692C>A p.D564E | Missense Mutation (SNP) | VAF 173/408 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ASF1B | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 255/611 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ATP10B | c.4016C>A p.P1339Q | Missense Mutation (SNP) | VAF 30/956 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2
- BAHD1 | c.210C>A p.C70* | Nonsense Mutation (SNP) | VAF 491/585 reads (84%) | called by muse, mutect2, varscan2
- BX276092.9 | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 22/738 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.363); called by muse, mutect2
- C16orf96 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 188/497 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC144A | c.4266G>T p.M1422I | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by mutect2, varscan2
- CDAN1 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 44/1057 reads (4%) | called by muse, mutect2
- CDH9 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 277/671 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CENPE | c.6283G>T p.E2095* | Nonsense Mutation (SNP) | VAF 38/1264 reads (3%) | called by muse, mutect2
- CEP170B | c.3878G>T p.S1293I (on ENST00000453495; = p.S1222I on NM_015005.3) | Missense Mutation (SNP) | VAF 29/440 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- CFAP65 | c.3855C>A p.F1285L | Missense Mutation (SNP) | VAF 19/552 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CH25H | c.509C>A p.A170E | Missense Mutation (SNP) | VAF 106/1184 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- CHD9 | c.935C>A p.S312* | Nonsense Mutation (SNP) | VAF 29/948 reads (3%) | called by muse, mutect2
- CHRD | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 261/337 reads (77%) | called by muse, mutect2, varscan2
- CIC | c.1917C>A p.F639L | Missense Mutation (SNP) | VAF 357/765 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLP1 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 347/429 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- COPG2 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 80/1064 reads (8%) | called by muse, mutect2
- CTAGE4 | c.828G>T p.M276I | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CYP11B2 | c.955-1G>T p.X319_splice | Splice Site (SNP) | VAF 29/576 reads (5%) | called by muse, mutect2
- DDX60 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 197/477 reads (41%) | called by muse, mutect2, varscan2
- DEGS2 | c.243C>A p.N81K | Missense Mutation (SNP) | VAF 200/603 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH6 | c.10699G>T p.E3567* | Nonsense Mutation (SNP) | VAF 14/395 reads (4%) | called by muse, mutect2
- DNAH7 | c.10574C>A p.S3525Y | Missense Mutation (SNP) | VAF 22/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- DNAJB13 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DNMT3B | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 206/550 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK4 | c.5298C>A p.S1766R | Missense Mutation (SNP) | VAF 104/1196 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2
- DPH2 | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 357/465 reads (77%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- DYNC2I2 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 217/509 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELOA3B | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 26/146 reads (18%) | called by mutect2, varscan2
- EML4 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 412/523 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB42 | c.26G>T p.S9I (on ENST00000441366 / NM_001114134.2; = p.S39I on NM_000119.3) | Missense Mutation (SNP) | VAF 34/1062 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2
- EPC1 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 71/1027 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- EPHB6 | c.2206G>T p.E736* | Nonsense Mutation (SNP) | VAF 287/699 reads (41%) | called by muse, mutect2, varscan2
- FAM186A | c.5578C>A p.Q1860K | Missense Mutation (SNP) | VAF 190/441 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBXW8 | c.1159G>T p.G387* (on ENST00000309909; = p.G425* on NM_012174.1) | Nonsense Mutation (SNP) | VAF 339/868 reads (39%) | called by muse, mutect2, varscan2
- FGB | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 383/884 reads (43%) | called by muse, mutect2, varscan2
- FILIP1 | c.1812G>T p.E604D | Missense Mutation (SNP) | VAF 351/458 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FIZ1 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 74/781 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.248); called by muse, mutect2
- FKRP | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 40/644 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.051); called by muse, mutect2
- FLRT3 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 302/745 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FNDC1 | c.1392G>T p.Q464H | Missense Mutation (SNP) | VAF 358/442 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by mutect2, varscan2
- FRAS1 | c.8129G>T p.C2710F | Missense Mutation (SNP) | VAF 285/786 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GAK | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- GALC | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 308/716 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GALNTL5 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 248/550 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDI1 | c.716C>A p.A239E | Missense Mutation (SNP) | VAF 350/831 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GIGYF1 | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 31/658 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GOLGA6L9 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 167/820 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- GPC2 | c.779G>T p.C260F | Missense Mutation (SNP) | VAF 326/760 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPN2 | c.861-1G>T p.X287_splice | Splice Site (SNP) | VAF 176/245 reads (72%) | called by muse, mutect2, varscan2
- GPX5 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 255/318 reads (80%) | called by muse, mutect2, varscan2
- GRIN3A | c.1955G>T p.S652I | Missense Mutation (SNP) | VAF 361/851 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR5B | c.3005G>T p.C1002F | Missense Mutation (SNP) | VAF 16/550 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); called by muse, mutect2
- HELZ | c.5454C>A p.C1818* | Nonsense Mutation (SNP) | VAF 435/585 reads (74%) | called by muse, mutect2, varscan2
- HHLA1 | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.32); called by muse, mutect2
- HSPA5 | c.1469C>A p.A490D | Missense Mutation (SNP) | VAF 247/672 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA9 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 430/1058 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ICE1 | c.5851C>A p.Q1951K | Missense Mutation (SNP) | VAF 224/579 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by mutect2, varscan2
- IL36RN | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 249/322 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- INSIG2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 22/625 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRF2BP1 | c.455G>T p.R152M | Missense Mutation (SNP) | VAF 326/729 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ITGB8 | c.805C>A p.H269N | Missense Mutation (SNP) | VAF 201/472 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- KIF22 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 230/601 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KNDC1 | c.3266G>T p.C1089F | Missense Mutation (SNP) | VAF 197/450 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LETM1 | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 158/648 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRCH1 | c.872C>A p.A291E | Missense Mutation (SNP) | VAF 115/352 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MAGEE1 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 84/1190 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by muse, mutect2
- MARCHF11 | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 369/925 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBOAT4 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2
- MFRP | c.533C>A p.A178E (on ENST00000449574; = p.A554E on NM_031433.4) | Missense Mutation (SNP) | VAF 441/546 reads (81%) | SIFT tolerated (0.46); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MKI67 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 276/704 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MLX | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 88/630 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MUC16 | c.41445C>A p.F13815L | Missense Mutation (SNP) | VAF 208/495 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MYO1D | c.1923G>T p.M641I | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2
- NDUFAF7 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 46/549 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- NLRP11 | c.-62-1G>T | Splice Site (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- NR2F1 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCDHB4 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 367/1103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PELI2 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 38/1080 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); called by muse, mutect2
- PFDN5 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 298/702 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- PHLDA1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 432/893 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHLDB2 | c.2842A>G p.K948E (on ENST00000393925 / NM_001134439.2; = p.K905E on NM_145753.2) | Missense Mutation (SNP) | VAF 438/556 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PIGT | c.876G>T p.E292D | Missense Mutation (SNP) | VAF 26/1008 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- PLEK | c.798C>A p.F266L | Missense Mutation (SNP) | VAF 179/227 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PNPLA7 | c.1361C>A p.A454D | Missense Mutation (SNP) | VAF 370/955 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- POFUT1 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 491/1131 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRKAA2 | c.1586C>A p.S529* | Nonsense Mutation (SNP) | VAF 85/632 reads (13%) | called by muse, mutect2, varscan2
- PRKDC | c.4259G>T p.R1420I | Missense Mutation (SNP) | VAF 173/441 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PRPF8 | c.4180C>A p.Q1394K | Missense Mutation (SNP) | VAF 48/516 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.15); called by muse, mutect2
- PRSS56 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2
- PSMG3 | c.236C>A p.A79E | Missense Mutation (SNP) | VAF 346/922 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PURA | c.935_938delinsGTTA p.L312_L313delinsR* | Nonsense Mutation (ONP) | VAF 96/711 reads (14%) | called by mutect2*, pindel, varscan2*
- PXDN | c.951C>A p.C317* | Nonsense Mutation (SNP) | VAF 65/568 reads (11%) | called by muse, mutect2, varscan2
- RACGAP1 | c.1594C>A p.L532I | Missense Mutation (SNP) | VAF 319/771 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- RALGDS | c.1358G>T p.S453I | Missense Mutation (SNP) | VAF 442/1074 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); called by muse, mutect2
- RBM15 | c.676_694del p.E226Sfs*14 | Frame Shift Del (DEL) | VAF 180/258 reads (70%) | called by mutect2, pindel*, varscan2
- RDX | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 419/523 reads (80%) | called by mutect2, varscan2
- REN | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 186/248 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.282); called by mutect2, varscan2
- RESF1 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 137/597 reads (23%) | called by muse, mutect2, varscan2
- RGS3 | c.652C>A p.L218I (on ENST00000350696 / NM_001282923.2; = p.L106I on NM_017790.4) | Missense Mutation (SNP) | VAF 258/631 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SCAF8 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 367/490 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAMP3 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2
- SCN7A | c.4993G>T p.E1665* | Nonsense Mutation (SNP) | VAF 182/482 reads (38%) | called by muse, mutect2, varscan2
- SERPINA1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 437/989 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SHROOM4 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 462/995 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- SIPA1L3 | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 213/513 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SLCO1B3 | c.1621C>A p.Q541K | Missense Mutation (SNP) | VAF 277/775 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SOHLH2 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- SORBS2 | c.3214G>T p.E1072* (on ENST00000284776 / NM_021069.5; = p.E638* on NM_003603.6) | Nonsense Mutation (SNP) | VAF 267/672 reads (40%) | called by muse, mutect2, varscan2
- SORL1 | c.2731G>T p.A911S | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by mutect2, varscan2
- SPAM1 | c.1424C>A p.T475K | Missense Mutation (SNP) | VAF 48/966 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- SREBF2 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 391/508 reads (77%) | SIFT tolerated (0.94); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SRRM1 | c.2611-1G>T p.X871_splice | Splice Site (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- STAG1 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 256/320 reads (80%) | called by mutect2, varscan2
- TAOK1 | c.2011C>A p.Q671K | Missense Mutation (SNP) | VAF 354/504 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- TBC1D2B | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 40/602 reads (7%) | called by muse, mutect2
- TCP11L1 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 306/405 reads (76%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); called by mutect2, varscan2
- TCTE1 | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TDRD12 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 203/503 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD6 | c.3168G>T p.E1056D | Missense Mutation (SNP) | VAF 141/361 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- TFR2 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 503/1349 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THOC2 | c.3085G>T p.A1029S | Missense Mutation (SNP) | VAF 346/799 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- TMC3 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 431/1005 reads (43%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TMC5 | c.2350C>A p.Q784K (on ENST00000396229 / NM_001105248.1; = p.Q538K on NM_024780.5) | Missense Mutation (SNP) | VAF 360/795 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEFF1 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 174/811 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- TMEM131 | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 319/421 reads (76%) | called by muse, mutect2, varscan2
- TMEM267 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 322/823 reads (39%) | called by muse, mutect2, varscan2
- TMEM41B | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM8B | c.141C>A p.D47E | Missense Mutation (SNP) | VAF 214/510 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TNXB | c.7568C>A p.A2523D (on ENST00000647633; = p.A2276D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/798 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- TPR | c.917C>A p.A306E | Missense Mutation (SNP) | VAF 47/433 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TRIM5 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 220/567 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC16 | c.1128C>A p.F376L | Missense Mutation (SNP) | VAF 268/645 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC6 | c.339G>T p.E113D (on ENST00000267368; = p.E1382D on NM_001310135.3) | Missense Mutation (SNP) | VAF 186/485 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- UBR5 | c.3928G>T p.E1310* | Nonsense Mutation (SNP) | VAF 229/288 reads (80%) | called by muse, mutect2, varscan2
- UPK1B | c.762C>A p.Y254* | Nonsense Mutation (SNP) | VAF 261/348 reads (75%) | called by mutect2, varscan2
- URGCP | c.1813C>A p.P605T (on ENST00000453200 / NM_001077663.3; = p.P596T on NM_017920.4) | Missense Mutation (SNP) | VAF 309/828 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.036); called by muse, mutect2
- USP19 | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 23/673 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.308); called by muse, mutect2
- USP43 | c.1536-4G>T | Splice Region (SNP) | VAF 60/146 reads (41%) | called by muse, mutect2, varscan2
- WDTC1 | c.2017C>A p.Q673K (on ENST00000319394 / NM_001276252.2; = p.Q672K on NM_015023.5) | Missense Mutation (SNP) | VAF 22/601 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- XKR6 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 201/244 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZBTB33 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 22/830 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- ZHX3 | c.1761C>A p.C587* | Nonsense Mutation (SNP) | VAF 38/1073 reads (4%) | called by muse, mutect2
- ZMYM6 | c.2650C>A p.Q884K | Missense Mutation (SNP) | VAF 40/681 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- ZNF17 | c.1668C>A p.C556* | Nonsense Mutation (SNP) | VAF 472/983 reads (48%) | called by muse, mutect2, varscan2
- ZNF251 | c.1579C>A p.H527N | Missense Mutation (SNP) | VAF 216/300 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF416 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 151/718 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ZNF667 | c.1123C>A p.L375M | Missense Mutation (SNP) | VAF 42/703 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNRD2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 264/353 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ABI1 | c.507C>A p.G169= | Silent (SNP) | VAF 188/493 reads (38%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.4455G>T p.V1485= | Silent (SNP) | VAF 324/766 reads (42%) | called by muse, mutect2, varscan2
- ALDH16A1 | c.480G>T p.L160= | Silent (SNP) | VAF 373/960 reads (39%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.1248G>T p.L416= | Silent (SNP) | VAF 345/853 reads (40%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.513G>T p.L171= (on ENST00000359920 / NM_001130955.2; = p.L67= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 215/536 reads (40%) | called by muse, mutect2, varscan2
- ARVCF | c.225C>A p.G75= | Silent (SNP) | VAF 347/445 reads (78%) | called by muse, mutect2, varscan2
- BAHCC1 | c.3690C>A p.S1230= | Silent (SNP) | VAF 13/458 reads (3%) | called by muse, mutect2
- CCKAR | c.1104C>A p.I368= | Silent (SNP) | VAF 55/713 reads (8%) | catalogued as COSV55162149; called by muse, mutect2
- CIDEB | c.594C>A p.S198= | Silent (SNP) | VAF 30/1098 reads (3%) | called by muse, mutect2
- FCRLB | c.231G>T p.V77= | Silent (SNP) | VAF 17/456 reads (4%) | called by muse, mutect2
- FSTL4 | c.816C>A p.V272= | Silent (SNP) | VAF 90/910 reads (10%) | called by muse, mutect2
- GABBR1 | c.432C>A p.I144= | Silent (SNP) | VAF 32/712 reads (4%) | catalogued as COSV100589834; called by muse, mutect2
- GALNT2 | c.411C>A p.A137= | Silent (SNP) | VAF 335/418 reads (80%) | called by muse, mutect2, varscan2
- GDNF | c.51G>T p.A17= | Silent (SNP) | VAF 540/1159 reads (47%) | catalogued as COSV58482076; called by muse, mutect2, varscan2
- HEBP1 | c.168G>T p.R56= | Silent (SNP) | VAF 269/612 reads (44%) | called by muse, mutect2, varscan2
- HEPH | c.216C>A p.T72= (on ENST00000343002; = p.T126= on NM_138737.5) | Silent (SNP) | VAF 253/666 reads (38%) | called by muse, mutect2, varscan2
- INTS14 | c.819C>A p.V273= (on ENST00000313182 / NM_001366360.2; = p.V194= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 435/489 reads (89%) | called by muse, mutect2, varscan2
- IPO7 | c.534G>T p.L178= | Silent (SNP) | VAF 310/410 reads (76%) | called by muse, mutect2, varscan2
- ITIH2 | c.1710G>A p.S570= | Silent (SNP) | VAF 454/1107 reads (41%) | catalogued as rs537160383, COSV64435228; called by muse, mutect2, varscan2
- KCNJ10 | c.903G>T p.L301= | Silent (SNP) | VAF 421/533 reads (79%) | called by muse, mutect2, varscan2
- KIF1B | c.3732C>A p.G1244= (on ENST00000377086 / NM_001365952.1; = p.G1198= on NM_015074.3) | Silent (SNP) | VAF 299/404 reads (74%) | catalogued as COSV55817453; called by muse, mutect2, varscan2
- KIF26A | c.2934G>T p.R978= | Silent (SNP) | VAF 275/538 reads (51%) | called by muse, mutect2, varscan2
- KLC2 | c.309G>T p.V103= | Silent (SNP) | VAF 316/412 reads (77%) | called by muse, mutect2, varscan2
- KRTAP10-8 | c.621C>A p.S207= | Silent (SNP) | VAF 118/363 reads (33%) | called by muse, mutect2, varscan2
- LINGO2 | c.1608G>T p.L536= | Silent (SNP) | VAF 375/922 reads (41%) | called by muse, mutect2, varscan2
- LRBA | c.6747C>A p.V2249= | Silent (SNP) | VAF 220/611 reads (36%) | catalogued as COSV63960938; called by muse, mutect2, varscan2
- LYSMD4 | c.399G>T p.L133= (on ENST00000409796 / NM_001284417.2; = p.L134= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 226/528 reads (43%) | called by mutect2, varscan2
- NEB | c.16494G>T p.L5498= | Silent (SNP) | VAF 20/710 reads (3%) | called by muse, mutect2
- NOL6 | c.2112C>A p.V704= | Silent (SNP) | VAF 368/866 reads (42%) | called by muse, mutect2, varscan2
- NOL8 | c.618G>T p.R206= | Silent (SNP) | VAF 323/743 reads (43%) | called by muse, mutect2, varscan2
- NPC1L1 | c.2268C>A p.I756= | Silent (SNP) | VAF 306/706 reads (43%) | catalogued as COSV56922553; called by muse, mutect2, varscan2
- OR4K14 | c.102C>A p.V34= | Silent (SNP) | VAF 197/488 reads (40%) | catalogued as COSV100520336; called by muse, mutect2, varscan2
- PGBD1 | c.291C>A p.P97= | Silent (SNP) | VAF 33/427 reads (8%) | called by muse, mutect2
- PLB1 | c.1656G>T p.L552= | Silent (SNP) | VAF 56/373 reads (15%) | called by muse, mutect2, varscan2
- POU2F2 | c.51G>T p.L17= | Silent (SNP) | VAF 204/537 reads (38%) | called by muse, mutect2, varscan2
- PPRC1 | c.1209C>A p.P403= | Silent (SNP) | VAF 40/580 reads (7%) | called by muse, mutect2
- RBM20 | c.2346C>A p.S782= | Silent (SNP) | VAF 34/922 reads (4%) | called by muse, mutect2
- RYR1 | c.13704C>A p.L4568= | Silent (SNP) | VAF 318/778 reads (41%) | called by muse, mutect2, varscan2
- SFRP5 | c.174C>A p.A58= | Silent (SNP) | VAF 139/355 reads (39%) | called by muse, mutect2, varscan2
- SLC13A4 | c.507C>A p.G169= | Silent (SNP) | VAF 74/1112 reads (7%) | catalogued as rs1260443598; called by muse, mutect2
- SLC8A1 | c.2850C>A p.L950= | Silent (SNP) | VAF 32/566 reads (6%) | called by muse, mutect2
- STBD1 | c.741G>T p.V247= | Silent (SNP) | VAF 42/614 reads (7%) | catalogued as rs755841996; called by muse, mutect2
- SUPT5H | c.375G>T p.L125= | Silent (SNP) | VAF 249/624 reads (40%) | called by muse, mutect2, varscan2
- TIMM44 | c.427C>A p.R143= | Silent (SNP) | VAF 69/1112 reads (6%) | catalogued as COSV54493528, COSV99564009; called by muse, mutect2
- TMEM74B | c.246C>A p.G82= | Silent (SNP) | VAF 21/533 reads (4%) | called by muse, mutect2
- ZMYND8 | c.2442G>T p.V814= (on ENST00000311275 / NM_001363741.2; = p.V834= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 401/1012 reads (40%) | called by muse, varscan2
- ZNF212 | c.894G>T p.L298= | Silent (SNP) | VAF 260/621 reads (42%) | called by muse, mutect2, varscan2
- ABCB7 | c.*55G>T | 3'UTR (SNP) | VAF 92/209 reads (44%) | called by muse, mutect2, varscan2
- ANKRD30B | c.*67G>T | 3'UTR (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- ANKRD33 | c.-71C>A | 5'UTR (SNP) | VAF 352/926 reads (38%) | called by muse, mutect2, varscan2
- ANXA13 | c.-11G>T | 5'UTR (SNP) | VAF 202/259 reads (78%) | called by muse, mutect2, varscan2
- AP1G2 | c.742-9C>A | Intron (SNP) | VAF 181/386 reads (47%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.61-57C>A | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- B4GALT1 | c.-37C>A | 5'UTR (SNP) | VAF 103/257 reads (40%) | called by muse, mutect2, varscan2
- CAMTA2 | c.-106G>T | 5'UTR (SNP) | VAF 15/501 reads (3%) | catalogued as rs1230726259; called by muse, mutect2
- CC2D2A | c.3014+17C>A | Intron (SNP) | VAF 88/245 reads (36%) | called by muse, mutect2, varscan2
- CD2BP2 | c.218-46C>A | Intron (SNP) | VAF 499/1130 reads (44%) | called by muse, mutect2, varscan2
- CENPK | c.*43C>A | 3'UTR (SNP) | VAF 13/375 reads (3%) | catalogued as COSV99669398, COSV99669494; called by muse, mutect2
- CHMP4A | c.359+44G>T | Intron (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- CSH2 | c.457-19C>A | Intron (SNP) | VAF 419/595 reads (70%) | called by muse, mutect2, varscan2
- CXCL12 | c.*144C>A | 3'UTR (SNP) | VAF 87/216 reads (40%) | catalogued as COSV100638921; called by muse, mutect2, varscan2
- CYP4F12 | c.*14C>A | 3'UTR (SNP) | VAF 36/768 reads (5%) | called by muse, mutect2
- DOCK1 | c.1139-21G>T | Intron (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- DUS1L | c.*76G>T | 3'UTR (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- EIF2AK4 | c.*58G>T | 3'UTR (SNP) | VAF 112/218 reads (51%) | called by mutect2, varscan2
- EIF5 | c.155-51C>A | Intron (SNP) | VAF 59/108 reads (55%) | called by muse, mutect2, varscan2
- EMC3-AS1 | chr3:10008393 C>A | 3'Flank (SNP) | VAF 203/264 reads (77%) | called by muse, mutect2, varscan2
- FBXO17 | c.462-50C>A | Intron (SNP) | VAF 7/144 reads (5%) | catalogued as rs1234929355; called by muse, mutect2
- FGA | c.1891+73C>A | Intron (SNP) | VAF 122/234 reads (52%) | called by mutect2, varscan2
- FGFRL1 | chr4:1012435 C>A | 5'Flank (SNP) | VAF 22/361 reads (6%) | called by muse, mutect2
- GEMIN5 | c.662-69C>A | Intron (SNP) | VAF 72/178 reads (40%) | called by muse, mutect2, varscan2
- GFOD2 | c.259+54C>A | Intron (SNP) | VAF 217/547 reads (40%) | called by muse, mutect2, varscan2
- GIMAP7 | c.*9G>T | 3'UTR (SNP) | VAF 181/466 reads (39%) | called by muse, mutect2, varscan2
- GPR65 | c.-19C>A | 5'UTR (SNP) | VAF 55/136 reads (40%) | called by mutect2, varscan2
- HNRNPM | c.113+33G>T | Intron (SNP) | VAF 24/283 reads (8%) | called by muse, mutect2
- IL17RB | c.946+25C>A | Intron (SNP) | VAF 32/413 reads (8%) | called by muse, mutect2
- INPP5J | c.1495-12C>A | Intron (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- KIF1A | c.3163-57C>A | Intron (SNP) | VAF 229/271 reads (85%) | called by muse, mutect2, varscan2
- KRT81 | c.*71C>A | 3'UTR (SNP) | VAF 82/195 reads (42%) | called by muse, mutect2
- MCM7 | c.277-42C>A | Intron (SNP) | VAF 95/240 reads (40%) | called by muse, mutect2, varscan2
- MEOX1 | c.*14G>T | 3'UTR (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- MS4A6A | c.282+81C>A | Intron (SNP) | VAF 195/246 reads (79%) | called by muse, mutect2
- MYO1F | c.414+28C>A | Intron (SNP) | VAF 174/347 reads (50%) | called by muse, mutect2, varscan2
- MYOT | c.531+63G>T | Intron (SNP) | VAF 81/163 reads (50%) | called by muse, mutect2, varscan2
- NME1-NME2 | c.546+24C>A | Intron (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- PCGF2 | c.-13C>A | 5'UTR (SNP) | VAF 21/195 reads (11%) | called by muse, mutect2, varscan2
- PCK1 | c.1318+22G>T | Intron (SNP) | VAF 402/901 reads (45%) | called by muse, mutect2, varscan2
- PIWIL3 | c.102+18G>T | Intron (SNP) | VAF 248/322 reads (77%) | called by muse, mutect2, varscan2
- PKD2 | c.710-69G>T | Intron (SNP) | VAF 158/328 reads (48%) | called by muse, mutect2, varscan2
- POLN | c.2387+95C>A | Intron (SNP) | VAF 72/181 reads (40%) | called by muse, mutect2, varscan2
- PTGR2 | c.729+11G>T | Intron (SNP) | VAF 113/298 reads (38%) | called by muse, mutect2, varscan2
- RASSF4 | c.-6G>T | 5'UTR (SNP) | VAF 173/478 reads (36%) | called by muse, mutect2, varscan2
- SLC22A17 | n.709-85C>A | Intron (SNP) | VAF 78/196 reads (40%) | called by muse, mutect2, varscan2
- SLC36A4 | c.179+74G>T | Intron (SNP) | VAF 48/55 reads (87%) | called by muse, mutect2, varscan2
- STXBP3 | c.258+43C>A | Intron (SNP) | VAF 188/255 reads (74%) | called by muse, mutect2, varscan2
- TBCD | c.3192-40C>A | Intron (SNP) | VAF 55/89 reads (62%) | catalogued as rs1370739029; called by muse, mutect2, varscan2
- TRMT6 | c.1215+39G>T | Intron (SNP) | VAF 194/443 reads (44%) | called by muse, mutect2, varscan2
- TTC22 | c.859-56C>A | Intron (SNP) | VAF 103/143 reads (72%) | called by muse, mutect2, varscan2
- UBXN10 | c.*83C>A | 3'UTR (SNP) | VAF 51/64 reads (80%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071977 C>A | 3'Flank (SNP) | VAF 36/761 reads (5%) | called by muse, mutect2
- VTA1 | c.*19C>A | 3'UTR (SNP) | VAF 281/405 reads (69%) | catalogued as COSV100859211; called by muse, mutect2, varscan2
- WDR45 | c.235+50C>A | Intron (SNP) | VAF 123/287 reads (43%) | called by muse, mutect2, varscan2
- ZNF414 | c.316+21C>A | Intron (SNP) | VAF 156/368 reads (42%) | catalogued as rs112277176; called by muse, mutect2, varscan2
- ZNF418 | c.*41C>A | 3'UTR (SNP) | VAF 87/256 reads (34%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776062 C>A | 5'Flank (SNP) | VAF 219/579 reads (38%) | catalogued as COSV50489522; called by muse, mutect2, varscan2
- ZNF641 | c.562+66G>T | Intron (SNP) | VAF 54/618 reads (9%) | catalogued as rs139421574; called by muse, mutect2
